Somatic mutation profile of tumor specimen ALCH-B3AU-TTP1-A (aliquot ALCH-B3AU-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3AU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.0 years (18,980 days).
Specimen ALCH-B3AU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25b62fd9-7962-473f-897e-ae67ca5085f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AU-NB1-A (Blood Derived Normal), aliquot ALCH-B3AU-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09fcee50-0ed7-4939-b4c5-fce086283930

The open-access MAF lists 183 somatic variants for this specimen: 126 protein-altering or splice-affecting, 30 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 30, Intron 16, Nonsense Mutation 10, 3'UTR 6, 5'UTR 2, Splice Region 2, 3'Flank 2, Translation Start Site 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057524439, CD134907; ClinVar: likely pathogenic; called by muse, mutect2
- AC013489.1 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1396656443; called by mutect2, varscan2
- AMACR | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV56874000; called by muse, mutect2
- ANKRD11 | c.7168C>T p.Q2390* | Nonsense Mutation (SNP) | VAF 14/333 reads (4%) | catalogued as COSV56358865; called by muse, mutect2
- ARHGDIB | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1042106739, COSV56762404; called by muse, mutect2
- ARHGEF10 | c.1221C>G p.I407M (on ENST00000398564; = p.I382M on NM_014629.4) | Missense Mutation (SNP) | VAF 24/771 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs1194442135, COSV50671493; called by muse, mutect2
- BAG5 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.237); catalogued as COSV54573041, COSV99914779; called by muse, mutect2
- BMP5 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1177138023; called by muse, mutect2
- C19orf71 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs764052909; called by muse, mutect2, varscan2
- CASTOR2 | c.906C>G p.F302L | Missense Mutation (SNP) | VAF 34/747 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs1346430095; called by muse, mutect2
- CCAR1 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV56269042, COSV56269630; called by muse, mutect2
- CCDC77 | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV53472492; called by muse, mutect2
- CCT8 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54506247; called by muse, mutect2
- CDKN2A | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 45/684 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; called by muse, mutect2
- COQ6 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 60/1022 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146408955; called by muse, mutect2
- DDC | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 46/883 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs931702374, COSV63563602; called by muse, mutect2
- DMRTA1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.226); catalogued as rs1245209816; called by muse, mutect2
- DPYD | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 27/468 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60077071; called by muse, mutect2
- DST | c.15256G>C p.D5086H (on ENST00000361203 / NM_001374722.1; = p.D2674H on NM_015548.5) | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55026626; called by muse, mutect2
- DSTYK | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65685207; called by muse, mutect2
- DUOXA2 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 43/846 reads (5%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.815); catalogued as rs1371612087; called by muse, mutect2
- EDRF1 | c.937G>A p.E313K (on ENST00000356792 / NM_001202438.2; = p.E279K on NM_015608.2) | Missense Mutation (SNP) | VAF 52/684 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV61763375; called by muse, mutect2
- ENTR1 | c.710C>T p.S237F (on ENST00000357365 / NM_001039707.2; = p.S214F on NM_006643.4) | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs1226047826, COSV53742995; called by muse, mutect2
- ERICH3 | c.3594C>A p.S1198R | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100443958; called by muse, mutect2
- ETV2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1435567426, COSV55837536, COSV55838312; called by muse, mutect2
- FBLN2 | c.2526C>G p.I842M | Missense Mutation (SNP) | VAF 23/591 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs1489460628; called by muse, mutect2
- FLG | c.3504C>A p.H1168Q | Missense Mutation (SNP) | VAF 64/684 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs766224121, COSV64253335; called by muse, mutect2
- GCK | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 40/698 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as CM081278; called by muse, mutect2
- GLDN | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291075541; called by muse, mutect2
- GNAZ | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50738641; called by muse, mutect2
- GRIP1 | c.1879G>A p.D627N (on ENST00000359742 / NM_001379345.1; = p.D575N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); catalogued as COSV54045109; called by muse, mutect2
- GTSE1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1253416584; called by muse, mutect2
- LMBR1 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 12/295 reads (4%) | catalogued as rs1233438390; called by muse, mutect2
- LRRK2 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54153989, COSV54155067; called by muse, mutect2
- MAP3K10 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 30/594 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99455058; called by muse, mutect2
- MED26 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54661584; called by muse, mutect2, varscan2
- MPP2 | c.667G>A p.A223T (on ENST00000461854 / NM_001278372.2; = p.A199T on NM_005374.5) | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs1255356198, COSV52235929; called by muse, mutect2
- MSLNL | c.2018C>G p.S673* | Nonsense Mutation (SNP) | VAF 24/672 reads (4%) | catalogued as COSV53499289; called by muse, mutect2
- MUC1 | c.3373G>A p.E1125K (on ENST00000611571 / NM_001371720.1; = p.E136K on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.316); catalogued as COSV100104536; called by muse, mutect2
- PADI1 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV64938152; called by muse, mutect2
- PANX1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1360256377; called by muse, mutect2
- PODXL2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 24/640 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as rs1449844076, COSV100686587; called by muse, mutect2
- RAB11FIP1 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as COSV54763818; called by muse, mutect2
- SLC34A2 | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 39/726 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV65940559; called by muse, mutect2
- SPATA13 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV57979010; called by muse, mutect2
- TAF1L | c.3176G>C p.G1059A | Missense Mutation (SNP) | VAF 14/490 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54267564; called by muse, mutect2
- TRIM16L | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV67459332; called by muse, mutect2
- ZNF791 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV58480864; called by muse, mutect2
- ABCB6 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABCD4 | c.1554G>C p.W518C | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2
- ADO | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.324); called by muse, mutect2
- ANK3 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 16/481 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF11 | c.1818G>C p.E606D | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); called by muse, mutect2
- ARMC4 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2
- CAVIN2 | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 33/625 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CCDC148 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 32/781 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- CDC5L | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CDCP2 | c.1174C>G p.Q392E | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CDKN2A | c.457+3G>T | Splice Region (SNP) | VAF 46/620 reads (7%) | called by muse, mutect2
- CSMD2 | c.8158G>C p.E2720Q | Missense Mutation (SNP) | VAF 31/521 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.653); called by muse, mutect2
- CTPS2 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2
- CYP2A13 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- CYP2C8 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 19/568 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM149B1 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 26/616 reads (4%) | called by muse, mutect2
- FAM178B | c.1738G>C p.E580Q (on ENST00000490605 / NM_001122646.3; = p.E20Q on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.308); called by muse, mutect2
- FBN2 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 23/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FIGNL1 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLG | c.3505C>A p.P1169T | Missense Mutation (SNP) | VAF 64/676 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.026); called by muse, mutect2
- FRMPD1 | c.2894C>G p.S965* | Nonsense Mutation (SNP) | VAF 13/263 reads (5%) | called by muse, mutect2
- FRY | c.7491G>C p.Q2497H | Missense Mutation (SNP) | VAF 16/521 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2
- GPATCH2 | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HNRNPA1 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2
- IFI16 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2
- ISCU | c.319G>C p.E107Q (on ENST00000311893 / NM_213595.4; = p.E82Q on NM_014301.4) | Missense Mutation (SNP) | VAF 18/626 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ISY1-RAB43 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2
- KCNJ5 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2
- KIFBP | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- LNPK | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LY9 | c.1920G>C p.Q640H | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MARS2 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 27/524 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2
- MTMR9 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.046); called by muse, mutect2
- NEO1 | c.3411G>A p.K1137= | Splice Region (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- NES | c.4744G>C p.E1582Q | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2
- NUDT18 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- OR2L8 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ORC1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 19/437 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- PCDHA6 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGA8 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.082); called by muse, mutect2
- PDE6A | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 29/683 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.253); called by muse, mutect2
- PDE6A | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2
- PIEZO1 | c.5150G>A p.W1717* | Nonsense Mutation (SNP) | VAF 12/293 reads (4%) | called by muse, mutect2
- PITX2 | c.686C>T p.S229L (on ENST00000354925 / NM_001204397.1; = p.S236L on NM_000325.6) | Missense Mutation (SNP) | VAF 20/391 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2
- PLXNA1 | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 26/472 reads (6%) | called by muse, mutect2
- RAB11FIP1 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2
- RABIF | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- RET | c.3036G>C p.R1012S | Missense Mutation (SNP) | VAF 33/917 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RPS15 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 34/612 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2
- RSU1 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.233); called by muse, mutect2
- RTN1 | c.1826T>A p.L609Q | Missense Mutation (SNP) | VAF 20/612 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- S100A7L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/231 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- SALL1 | c.2623G>T p.A875S | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.186); called by muse, mutect2
- SBF1 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- SCN3A | c.2833A>G p.I945V | Missense Mutation (SNP) | VAF 67/1229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA6C | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2
- SENP2 | c.1020G>C p.R340S | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.373); called by muse, mutect2
- SERPINE1 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 17/272 reads (6%) | called by muse, mutect2
- SERPINE1 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 23/571 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SHPRH | c.4574G>C p.R1525T (on ENST00000275233 / NM_001042683.3; = p.R1529T on NM_173082.3) | Missense Mutation (SNP) | VAF 34/649 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- SLC27A2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.005); called by muse, mutect2
- SLC36A2 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 21/784 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- SLURP1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 42/852 reads (5%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.086); called by muse, mutect2
- SPI1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2
- SZT2 | c.10152G>C p.K3384N (on ENST00000634258 / NM_001365999.1; = p.K3327N on NM_015284.4) | Missense Mutation (SNP) | VAF 21/537 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- THSD7B | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 24/636 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); called by muse, mutect2
- TIGD5 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2
- TMEM179B | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2
- TRAF5 | c.-1-1G>C | Splice Site (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- TRIM33 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- TRIP12 | c.5906C>G p.S1969* | Nonsense Mutation (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- TTYH2 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); called by muse, mutect2
- USHBP1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2
- UTRN | c.5980G>C p.E1994Q | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZCCHC8 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZCRB1 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2
- ZNF281 | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2
- ZNFX1 | c.2844G>C p.K948N | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.29); called by muse, mutect2
- ADAMTSL2 | c.1071G>T p.G357= | Silent (SNP) | VAF 36/466 reads (8%) | called by muse, mutect2
- C19orf73 | c.327C>G p.L109= | Silent (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- CARNS1 | c.1023G>A p.V341= | Silent (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- CMBL | c.474C>G p.V158= | Silent (SNP) | VAF 15/183 reads (8%) | catalogued as rs1271254328; called by muse, mutect2
- COL5A3 | c.4917G>C p.L1639= | Silent (SNP) | VAF 24/446 reads (5%) | called by muse, mutect2
- DGKI | c.1218C>G p.V406= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- DLGAP3 | c.861C>T p.F287= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- FAM47C | c.93G>A p.A31= | Silent (SNP) | VAF 10/312 reads (3%) | catalogued as rs868908339, COSV63724809; called by muse, mutect2
- FKRP | c.1464G>A p.L488= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as rs1196078520; called by muse, mutect2
- FOXD3 | c.486G>T p.L162= | Silent (SNP) | VAF 40/760 reads (5%) | called by muse, mutect2
- GPR85 | c.162A>T p.A54= | Silent (SNP) | VAF 22/500 reads (4%) | called by muse, mutect2
- GRIK4 | c.1338C>T p.G446= | Silent (SNP) | VAF 29/566 reads (5%) | called by muse, mutect2
- HERC6 | c.1044C>G p.V348= | Silent (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- HRNR | c.303G>C p.L101= | Silent (SNP) | VAF 24/278 reads (9%) | catalogued as rs773455208, COSV64255271, COSV64262925; called by muse, mutect2
- KREMEN1 | c.1478G>A p.*493= | Silent (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- MAGEF1 | c.264G>T p.L88= | Silent (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- MMACHC | c.9G>C p.P3= | Silent (SNP) | VAF 32/680 reads (5%) | called by muse, mutect2
- MS4A1 | c.690G>C p.L230= | Silent (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- NPAP1 | c.885G>A p.P295= | Silent (SNP) | VAF 12/189 reads (6%) | catalogued as COSV61509195; called by muse, mutect2
- NRXN3 | c.2304G>A p.G768= (on ENST00000335750 / NM_001330195.2; = p.G395= on NM_004796.6) | Silent (SNP) | VAF 18/405 reads (4%) | called by muse, mutect2
- OPN4 | c.735C>T p.F245= | Silent (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- PCDH19 | c.822C>G p.V274= | Silent (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2
- PHLPP2 | c.1416G>A p.L472= | Silent (SNP) | VAF 30/594 reads (5%) | called by muse, mutect2
- PKDREJ | c.3288A>G p.R1096= | Silent (SNP) | VAF 17/410 reads (4%) | called by muse, mutect2
- RAI2 | c.96G>A p.L32= | Silent (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- RIPOR2 | c.1500G>C p.L500= | Silent (SNP) | VAF 26/376 reads (7%) | called by muse, mutect2
- SH2D5 | c.165G>A p.L55= | Silent (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- SLC6A3 | c.1779C>T p.Y593= | Silent (SNP) | VAF 34/678 reads (5%) | catalogued as rs141485913; called by muse, mutect2
- TMEM63C | c.177C>T p.L59= | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- ZC3H4 | c.2457C>T p.S819= | Silent (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- AC105942.1 | n.1040-1638G>A | Intron (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
- ADAM1A | chr12:111901434 C>T | 3'Flank (SNP) | VAF 13/347 reads (4%) | called by muse, mutect2
- ANTXR1 | c.951+10410G>C | Intron (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- ASTN1 | c.1120+254C>T | Intron (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- CCHCR1 | c.-51-446C>T | Intron (SNP) | VAF 44/486 reads (9%) | called by muse, mutect2
- CDC5L | c.-31C>T | 5'UTR (SNP) | VAF 51/908 reads (6%) | catalogued as rs759264216; called by muse, mutect2
- CEP41 | c.*4448G>A | 3'UTR (SNP) | VAF 30/534 reads (6%) | called by muse, mutect2
- CILK1 | c.*27C>T | 3'UTR (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- CRACR2B | c.459-16C>G | Intron (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- CYTH4 | c.435-764G>C | Intron (SNP) | VAF 28/708 reads (4%) | called by muse, mutect2
- DZANK1 | c.379-68C>G | Intron (SNP) | VAF 15/355 reads (4%) | called by muse, mutect2
- EFCAB13 | c.-59C>G | 5'UTR (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- GJA3 | c.*6G>A | 3'UTR (SNP) | VAF 23/392 reads (6%) | called by muse, mutect2
- HTRA2 | c.906+10G>C | Intron (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
- IFNGR2 | c.722-37G>A | Intron (SNP) | VAF 21/337 reads (6%) | catalogued as rs17885089; called by muse, mutect2
- IL1B | c.597+32C>G | Intron (SNP) | VAF 30/562 reads (5%) | called by muse, mutect2
- NBPF11 | c.*203G>C | 3'UTR (SNP) | VAF 30/988 reads (3%) | called by muse, mutect2
- NDUFS7 | chr19:1383750 C>T | 5'Flank (SNP) | VAF 55/630 reads (9%) | catalogued as rs893203730; called by muse, mutect2
- PA2G4 | c.88+221G>C | Intron (SNP) | VAF 19/423 reads (4%) | called by muse, mutect2
- PHYKPL | c.60-263G>A | Intron (SNP) | VAF 18/514 reads (4%) | called by muse, mutect2
- PLAGL2 | chr20:32189914 T>A | 3'Flank (SNP) | VAF 18/332 reads (5%) | called by muse, mutect2
- PLOD1 | c.580-231C>T | Intron (SNP) | VAF 14/422 reads (3%) | catalogued as rs1186460137; called by muse, mutect2
- RESP18 | c.*5G>A | 3'UTR (SNP) | VAF 17/492 reads (3%) | called by muse, mutect2
- SHOC2 | c.-235+17100C>G | Intron (SNP) | VAF 54/890 reads (6%) | called by muse, mutect2
- SNRPG | c.32+429G>A | Intron (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- ZNF395 | c.*21C>T | 3'UTR (SNP) | VAF 27/717 reads (4%) | called by muse, mutect2
- ZSCAN32 | c.839-906C>T | Intron (SNP) | VAF 19/443 reads (4%) | catalogued as COSV59237637; called by muse, mutect2
